Gene-level copy-number profile of tumor specimen TCGA-BR-A4IY-01A from TCGA case TCGA-BR-A4IY, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 58.4 years (21,314 days).
Specimen TCGA-BR-A4IY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.7be3815b-380b-4b74-a462-81286b2ffe2a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-A4IY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9c458e7c-fc8a-443c-9a02-b128c5b9d074

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 8,712; copy number 2: 38,702; copy number 3: 10,093; copy number 4: 483; copy number 5: 1,347; copy number 6: 409; copy number 7: 44.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-A4IY-01A-11D-A253-01): tumor purity 0.36, ploidy 2.19, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,800 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:7,141,227–29,189,643, 408 genes, copy number 6 (broad region; genes not listed).
- chr2:29,319,554–29,352,214, 1 gene, copy number 6: AC074096.1.
- chr6:5,788,346–9,294,133, 58 genes, copy number 5–7: AL136968.2, AL136968.1, AL136307.1, RN7SL221P, PKMP5, NRN1, F13A1, MIR7853, MIR5683, LY86-AS1, SNAPC5P1, AL162719.1, CNN3P1, LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA, AL589644.1, AL139095.5, SSR1, AL139095.4, CAGE1, AL139095.1, AL139095.2, AL139095.3, RIOK1, HNRNPLP1, AL138878.1, AL138878.2, AL031058.1, DSP, SNRNP48, AL390026.1, BMP6, TXNDC5, BLOC1S5-TXNDC5, AL096800.1, PIP5K1P1, BLOC1S5, EEF1E1-BLOC1S5, EEF1E1, AL355499.1, AL355499.2, AL359378.1, SLC35B3, HULC, AL161437.1, AL137220.1.
- chr7:70,972–7,293,880, 182 genes, copy number 5 (broad region; genes not listed).
- chr7:32,580,949–43,113,931, 176 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr7:43,117,896–43,207,866, 4 genes, copy number 5: HECW1-IT1, MIR3943, RNU7-35P, RNU6-575P.
- chr7:109,763,574–145,584,817, 713 genes, copy number 5 (broad region; genes not listed).
- chr9:11,313,397–16,870,843, 62 genes, copy number 5 (broad region; genes not listed).
- chr16:84,974,175–90,222,851, 196 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,851. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
